Somatic mutation profile of tumor specimen TCGA-CM-6161-01A (aliquot TCGA-CM-6161-01A-11D-1650-10) from TCGA case TCGA-CM-6161, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 36.6 years (13,363 days).
Specimen TCGA-CM-6161-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) caee3c27-129f-4926-b56b-4863c0d8bd6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6161-10A (Blood Derived Normal), aliquot TCGA-CM-6161-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eaf3cfcc-7123-4361-ab54-17d3adc44473

The open-access MAF lists 101 somatic variants for this specimen: 70 protein-altering or splice-affecting, 30 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 30, Nonsense Mutation 4, Splice Site 1, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL1 | c.2909G>A p.R970Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1330626830, COSV65894822; called by muse, mutect2
- AHNAK2 | c.12238C>A p.L4080M | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.524); catalogued as COSV60906350; called by mutect2, varscan2
- AXIN1 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774345751, COSV51990914; called by muse, mutect2, varscan2
- B3GNTL1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779174616, COSV57952011; called by muse, mutect2, varscan2
- BCL9L | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780637963, COSV58317593; called by muse, mutect2, varscan2
- BEND4 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs759165820, COSV72469298; called by muse, mutect2, varscan2
- BPIFA2 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); catalogued as rs750572385, COSV53610580; called by muse, mutect2, varscan2
- BRIP1 | c.3413A>G p.D1138G | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1057518847, COSV99370672; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C21orf91 | c.394C>A p.L132I | Missense Mutation (SNP) | VAF 113/160 reads (71%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV53033366; called by muse, mutect2, varscan2
- CACNA1G | c.3703C>T p.R1235W | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs768623076, COSV61733936; called by muse, mutect2, varscan2
- CACNA2D3 | c.1291G>T p.V431F | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99875891; called by muse, mutect2
- CD177 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.408); catalogued as rs771651317, COSV100946030, COSV65121527; called by muse, mutect2, varscan2
- CDH13 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs766066852, COSV51789654, COSV51795232; called by muse, mutect2, varscan2
- COL6A1 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375217284; ClinVar: uncertain significance / benign; called by muse, varscan2
- CRYBG1 | c.3123G>C p.Q1041H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV64813717; called by muse, mutect2
- CRYBG3 | c.7979T>C p.L2660P | Missense Mutation (SNP) | VAF 167/857 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99477288; called by muse, mutect2, varscan2
- CSPG5 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs775179910, COSV53132244; called by muse, mutect2, varscan2
- DYNC1I1 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1381436803, COSV61458321; called by muse, varscan2
- ELL | c.920C>A p.A307D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99443574; called by muse, mutect2, varscan2
- FAT2 | c.3945G>A p.T1315= | Splice Region (SNP) | VAF 50/248 reads (20%) | catalogued as rs1449193613, COSV55826089; called by muse, mutect2, varscan2
- FURIN | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1482722393, COSV99184752; called by muse, mutect2, varscan2
- GAN | c.1589A>T p.Y530F | Missense Mutation (SNP) | VAF 214/603 reads (35%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); catalogued as COSV73721204; called by muse, mutect2, varscan2
- GLB1L | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs150577551; called by muse, mutect2, varscan2
- GPR85 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs761703405, COSV51783098; called by muse, mutect2, varscan2
- HECW1 | c.661A>G p.M221V | Missense Mutation (SNP) | VAF 100/224 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67836667; called by muse, mutect2, varscan2
- HRAS | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54245262; called by muse, mutect2, varscan2
- IFI44L | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs974783332, COSV60728784; called by muse, mutect2, varscan2
- IFRD1 | c.247A>T p.K83* | Nonsense Mutation (SNP) | VAF 33/158 reads (21%) | catalogued as COSV50044869; called by muse, mutect2, varscan2
- INTS1 | c.3907A>T p.T1303S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.713); catalogued as COSV67178912; called by muse, mutect2, varscan2
- ITGA6 | c.1372A>T p.T458S (on ENST00000442250; = p.T419S on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/387 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as COSV51241627; called by muse, mutect2, varscan2
- KIF1B | c.1993G>A p.E665K (on ENST00000377086 / NM_001365952.1; = p.E619K on NM_015074.3) | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV55813056; called by muse, mutect2, varscan2
- KLF5 | c.1024A>T p.N342Y | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.564); catalogued as COSV66615119; called by muse, mutect2, varscan2
- MARCHF4 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.366); catalogued as COSV56107091; called by muse, mutect2, varscan2
- MED12 | c.2363C>A p.A788E | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.392); catalogued as COSV61350751; called by muse, mutect2, varscan2
- MEIOB | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 196/628 reads (31%) | catalogued as rs35694423; called by muse, mutect2, varscan2
- MUC17 | c.12749A>G p.D4250G | Missense Mutation (SNP) | VAF 87/319 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as rs1377699474, COSV60298010; called by muse, mutect2, varscan2
- MUC6 | c.3653C>T p.T1218M | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs747792060, COSV70146839; called by muse, mutect2, varscan2
- OR14K1 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 36/742 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV51721980; called by muse, mutect2
- OR4K1 | c.896G>A p.W299* | Nonsense Mutation (SNP) | VAF 19/146 reads (13%) | catalogued as rs144917067; called by muse, mutect2, varscan2
- PAPLN | c.1210G>T p.A404S (on ENST00000554301; = p.A377S on NM_173462.4) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV53721623; called by muse, mutect2, varscan2
- PCDHB7 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as rs782375104, COSV99176127, COSV99177205; called by muse, mutect2, varscan2
- PILRA | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as COSV99546647; called by muse, mutect2, varscan2
- PLB1 | c.3368G>A p.R1123K | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.801); catalogued as COSV59832361; called by muse, mutect2, varscan2
- PRAMEF18 | c.287+1G>A p.X96_splice | Splice Site (SNP) | VAF 142/702 reads (20%) | catalogued as rs1213077430; called by muse, mutect2, varscan2
- PSME4 | c.2027A>T p.N676I | Missense Mutation (SNP) | VAF 126/541 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV104433273, COSV66366741; called by muse, mutect2, varscan2
- PTF1A | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV100919580; called by muse, mutect2, varscan2
- S100G | c.37A>T p.I13F | Missense Mutation (SNP) | VAF 104/415 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV63723584; called by muse, mutect2, varscan2
- SGCD | c.551C>A p.A184E (on ENST00000435422 / NM_001128209.2; = p.A185E on NM_000337.5) | Missense Mutation (SNP) | VAF 109/246 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61912988; called by muse, mutect2, varscan2
- SLC24A1 | c.1734C>A p.D578E | Missense Mutation (SNP) | VAF 88/370 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs762172630, COSV99978517; called by muse, mutect2, varscan2
- SLC24A3 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV60127443; called by muse, mutect2, varscan2
- SLC6A16 | c.371C>A p.S124Y | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.753); catalogued as COSV60028765, COSV60029332; called by muse, mutect2, varscan2
- STAT1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV63115091; called by muse, mutect2
- STK32C | c.1456G>A p.G486S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs780331333, COSV53843928; called by muse, mutect2, varscan2
- SV2C | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373545330; called by muse, mutect2, varscan2
- TGFBRAP1 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as rs372399291; called by muse, mutect2
- TIAM2 | c.5173G>C p.E1725Q (on ENST00000529824; = p.E1696Q on NM_012454.3) | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as rs751478746, COSV51643196; called by muse, mutect2, varscan2
- TRPC3 | c.785C>T p.P262L (on ENST00000379645 / NM_001366479.2; = p.P189L on NM_003305.2) | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571866879, COSV53377224; called by muse, mutect2, varscan2
- TTN | c.2422C>T p.R808C (on ENST00000591111; = p.R762C on NM_003319.4) | Missense Mutation (SNP) | VAF 61/268 reads (23%) | PolyPhen possibly damaging (0.862); catalogued as rs149155733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.10259T>G p.F3420C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.258); catalogued as COSV100239442; called by muse, mutect2, varscan2
- WASHC2C | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1554874485, COSV100314149; called by mutect2, varscan2
- WIPF3 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs746130389, COSV54211289; called by muse, varscan2
- ZAP70 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs776066014, COSV53855925; called by muse, mutect2, varscan2
- ZNF235 | c.1951G>A p.G651R | Missense Mutation (SNP) | VAF 156/308 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs757002688, COSV99349641; called by muse, varscan2
- ZNF480 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 39/81 reads (48%) | catalogued as rs538245309, COSV57996807; called by muse, mutect2, varscan2
- ZNF521 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs751157753, COSV64124837; called by muse, mutect2
- ZNF704 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs139476385; called by muse, mutect2, varscan2
- GLI1 | c.2918del p.N973Ifs*3 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | called by mutect2, pindel, varscan2
- KMT2C | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 35/395 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); called by muse, varscan2
- MSLN | c.367C>A p.L123M | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SCN8A | c.386dup p.L129Ffs*7 | Frame Shift Ins (INS) | VAF 24/100 reads (24%) | called by mutect2, pindel, varscan2
- ABCA13 | c.8058C>T p.N2686= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV71292409; called by muse, mutect2, varscan2
- AC008676.3 | c.9C>T p.I3= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs767226158, COSV56637485; called by muse, mutect2, varscan2
- ACTA1 | c.48C>T p.S16= | Silent (SNP) | VAF 21/190 reads (11%) | catalogued as rs370407621; called by muse, mutect2, varscan2
- AMPD2 | c.414G>A p.S138= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as rs763135190, COSV99857984; called by muse, mutect2, varscan2
- C1orf94 | c.1737C>T p.S579= (on ENST00000488417 / NM_001134734.2; = p.S389= on NM_032884.5) | Silent (SNP) | VAF 79/234 reads (34%) | catalogued as rs147248695; called by muse, mutect2, varscan2
- CDH23 | c.5112C>T p.H1704= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs774919846, COSV56480388; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL9A1 | c.2622C>T p.D874= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs149139869; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIDO1 | c.6066C>T p.G2022= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV56630555; called by muse, varscan2
- DOCK6 | c.5481G>A p.P1827= | Silent (SNP) | VAF 41/162 reads (25%) | catalogued as rs765316358, COSV53919518; ClinVar: likely benign; called by muse, mutect2, varscan2
- IFNAR2 | c.780C>G p.T260= | Silent (SNP) | VAF 60/228 reads (26%) | catalogued as COSV59750357; called by muse, mutect2
- INTS1 | c.3906G>A p.Q1302= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV67178481; called by muse, mutect2, varscan2
- LTF | c.1152C>T p.S384= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs138970012; called by muse, mutect2, varscan2
- MLIP | c.468C>T p.T156= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as rs746829040, COSV51425736; called by muse, mutect2, varscan2
- NBEA | c.5764C>T p.L1922= | Silent (SNP) | VAF 29/173 reads (17%) | catalogued as COSV59808577; called by muse, mutect2, varscan2
- PIGG | c.1521G>A p.A507= (on ENST00000453061 / NM_001127178.3; = p.A499= on NM_017733.4) | Silent (SNP) | VAF 141/406 reads (35%) | catalogued as rs765820128, COSV99574168, COSV99574272; ClinVar: uncertain significance; called by mutect2, varscan2
- PRKG2 | c.324G>A p.K108= | Silent (SNP) | VAF 51/161 reads (32%) | catalogued as COSV100020277; called by muse, mutect2, varscan2
- PSG9 | c.471C>T p.N157= | Silent (SNP) | VAF 56/233 reads (24%) | catalogued as rs777690483, COSV52486895; called by muse, mutect2, varscan2
- RIMBP2 | c.1482C>T p.T494= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs551946345, COSV99898333; called by muse, mutect2, varscan2
- SEMA4F | c.387C>T p.L129= | Silent (SNP) | VAF 74/272 reads (27%) | catalogued as rs1490931460, COSV60284647; called by muse, mutect2, varscan2
- SESN3 | c.324G>A p.R108= | Silent (SNP) | VAF 58/194 reads (30%) | catalogued as COSV53586567; called by muse, mutect2, varscan2
- SPEG | c.4140G>A p.L1380= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as rs1227111898, COSV56676372; called by muse, mutect2, varscan2
- STAC2 | c.615C>T p.Y205= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs201624343, COSV61066314; called by muse, mutect2, varscan2
- STK25 | c.1131C>T p.G377= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as rs772987757, COSV50876977; called by muse, mutect2, varscan2
- STON1 | c.372G>T p.L124= | Silent (SNP) | VAF 34/203 reads (17%) | catalogued as COSV59135183; called by muse, mutect2, varscan2
- THSD7A | c.1896G>T p.P632= | Silent (SNP) | VAF 112/427 reads (26%) | catalogued as COSV70270619, COSV70273677; called by muse, mutect2, varscan2
- TMPRSS11F | c.1117T>C p.L373= | Silent (SNP) | VAF 113/402 reads (28%) | catalogued as COSV62468218; called by muse, mutect2, varscan2
- TTN | c.19650C>T p.A6550= (on ENST00000591111; = p.A5623= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 95/159 reads (60%) | catalogued as rs374731328, COSV60281947; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZBTB21 | c.2238C>T p.N746= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs747522542, COSV60403510; called by muse, mutect2, varscan2
- ZC3H14 | c.168G>A p.G56= | Silent (SNP) | VAF 55/220 reads (25%) | catalogued as COSV99193168; called by muse, mutect2, varscan2
- ZFHX4 | c.4272G>A p.A1424= | Silent (SNP) | VAF 46/209 reads (22%) | catalogued as rs199795783; called by muse, mutect2, varscan2
- PKD1L2 | chr16:81139638 G>A | 5'Flank (SNP) | VAF 39/118 reads (33%) | catalogued as rs1191162147; called by muse, mutect2, varscan2
